Somatic mutation profile of tumor specimen TCGA-F4-6806-01A (aliquot TCGA-F4-6806-01A-11D-1835-10) from TCGA case TCGA-F4-6806, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage I; Age at diagnosis: 59.2 years (21,625 days).
Specimen TCGA-F4-6806-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7875f16f-d00e-4190-9545-f2af37119f5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-F4-6806-10A (Blood Derived Normal), aliquot TCGA-F4-6806-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f886d4f-5d0b-45ee-94ec-ec6f226fc4e6

The open-access MAF lists 117 somatic variants for this specimen: 81 protein-altering or splice-affecting, 34 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 63, Silent 34, Nonsense Mutation 8, Frame Shift Ins 4, In Frame Del 3, Frame Shift Del 2, Intron 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2805C>G p.Y935* | Nonsense Mutation (SNP) | VAF 25/63 reads (40%) | hotspot (GDC flag); catalogued as rs137854575, CD041148, CM920044, CM970086, COSV57324059, COSV57328770; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 39/121 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MTOR | c.6644C>T p.S2215F | Missense Mutation (SNP) | VAF 14/61 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs587777894, COSV63868278, COSV63868313; ClinVar: not provided / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- WT1 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.495); catalogued as rs121907903, CM041493, CM920718, CM982050, COSV60065677, COSV60065800, COSV60069955; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.2389T>A p.F797I | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as COSV66063624; called by muse, mutect2, varscan2
- ACVR1 | c.1123C>T p.R375C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751000395, COSV55116085; called by muse, mutect2
- ACVR1B | c.1330C>T p.R444* | Nonsense Mutation (SNP) | VAF 9/63 reads (14%) | catalogued as COSV57774850; called by muse, mutect2, varscan2
- ADGRL3 | c.1357G>A p.V453M (on ENST00000506720 / NM_001322402.2; = p.V385M on NM_015236.6) | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1298975938, COSV72265533; called by muse, mutect2, varscan2
- APC | c.4339C>T p.Q1447* | Nonsense Mutation (SNP) | VAF 22/92 reads (24%) | catalogued as COSV57336529, COSV57336541; called by muse, mutect2, varscan2
- B3GLCT | c.1330G>C p.A444P | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1374684270, COSV58452977, COSV58453222; called by muse, mutect2, varscan2
- BDKRB2 | c.731C>T p.T244M | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1239271323, COSV60013532; called by muse, mutect2, varscan2
- BGN | c.47C>A p.A16D | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59035878, COSV59038133; called by muse, mutect2, varscan2
- BNC2 | c.3238C>T p.R1080* | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | catalogued as COSV101036516; called by mutect2, varscan2
- BPIFB4 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as rs752406178, COSV64950589, COSV64950633; called by muse, mutect2, varscan2
- C7orf57 | c.770C>A p.P257H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as COSV100817307, COSV62364097; called by muse, mutect2, varscan2
- CAND1 | c.1691A>G p.Y564C | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV101607335; called by muse, mutect2, varscan2
- CBLN2 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV54050194, COSV54053259; called by muse, mutect2, varscan2
- CCDC91 | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.147); catalogued as COSV60338997; called by muse, mutect2, varscan2
- CCNY | c.228C>T p.D76= | Splice Region (SNP) | VAF 107/316 reads (34%) | catalogued as rs149125137; called by muse, mutect2, varscan2
- CLEC4D | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs374210290, COSV100222924, COSV55227887; called by muse, mutect2, varscan2
- COL10A1 | c.70C>T p.R24* | Nonsense Mutation (SNP) | VAF 83/210 reads (40%) | catalogued as rs199808053; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CP | c.2407_2409del p.E803del | In Frame Del (DEL) | VAF 10/43 reads (23%) | catalogued as rs1482869210; called by pindel, varscan2
- CYP2A7 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 8/56 reads (14%) | catalogued as rs200907719, COSV52497013; called by mutect2, varscan2
- DARS2 | c.137G>A p.S46N | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99508822; called by muse, mutect2
- DCTN1 | c.1807C>T p.H603Y | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.21); catalogued as COSV100720989; called by muse, mutect2, varscan2
- DUSP5 | c.640C>T p.R214W | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs144264318; called by muse, mutect2, varscan2
- EEF1AKMT3 | c.356A>T p.N119I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100103705; called by muse, mutect2, varscan2
- FAT2 | c.6350G>A p.R2117Q | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.933); catalogued as rs763727182, COSV55825497; called by muse, mutect2, varscan2
- FAT4 | c.11591A>T p.D3864V | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.713); catalogued as COSV100629303; called by muse, mutect2, varscan2
- FAT4 | c.13660G>T p.E4554* | Nonsense Mutation (SNP) | VAF 9/79 reads (11%) | catalogued as COSV58672571; called by muse, mutect2, varscan2
- FEM1A | c.1378G>A p.G460S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as rs776751127, COSV54162941; called by muse, mutect2, varscan2
- FETUB | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.039); catalogued as rs748755333, COSV54004568; called by muse, mutect2, varscan2
- GJB3 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs759759043, COSV64904378; called by muse, mutect2, varscan2
- H2AX | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.96); catalogued as COSV53827886; called by muse, mutect2, varscan2
- HIRIP3 | c.59A>G p.D20G | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99663194; called by muse, mutect2, varscan2
- HOXD3 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV50879735; called by muse, mutect2, varscan2
- ICE2 | c.2236T>C p.C746R | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55029657; called by muse, mutect2, varscan2
- ITCH | c.337C>T p.L113F | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs199947085, COSV52929185; called by muse, mutect2, varscan2
- KCND1 | c.1870G>A p.G624S | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0); catalogued as rs145016539, COSV54412357, COSV99502004; called by muse, mutect2, varscan2
- KCNH8 | c.2420C>T p.P807L | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.094); catalogued as COSV60456267; called by muse, mutect2, varscan2
- KCNJ3 | c.1333G>T p.G445C | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.781); catalogued as COSV54531195; called by muse, mutect2, varscan2
- KRT222 | c.736T>A p.S246T | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV67497721; called by muse, mutect2, varscan2
- LAMA3 | c.1774A>G p.I592V | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100557155; called by muse, mutect2
- MSL3 | c.1055C>T p.T352M (on ENST00000312196 / NM_078629.4; = p.T186M on NM_006800.4) | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as rs749183286, COSV56491429; called by muse, mutect2, varscan2
- MYO3A | c.3938G>A p.R1313H | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs142853143, COSV56319295; called by muse, mutect2, varscan2
- NDUFA9 | c.419A>G p.D140G | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as COSV99865828; called by muse, mutect2, varscan2
- NLGN4X | c.679C>T p.Q227* | Nonsense Mutation (SNP) | VAF 38/163 reads (23%) | catalogued as COSV52004022; called by muse, mutect2, varscan2
- OR10C1 | c.193C>T p.R65C (on ENST00000622521; = p.R63C on NM_013941.3) | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as rs755057225, COSV65822205; called by muse, mutect2, varscan2
- OSTN | c.364C>T p.R122W | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1053606942, COSV59138785; called by muse, mutect2, varscan2
- OTOF | c.5870T>C p.F1957S (on ENST00000272371 / NM_194248.3; = p.F1190S on NM_004802.4) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV99718260; called by muse, mutect2, varscan2
- PCDHA12 | c.1890G>T p.E630D | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.861); catalogued as COSV56476702, COSV56514161; called by muse, mutect2, varscan2
- PKDREJ | c.755C>T p.A252V | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs773366004, COSV99478700; called by mutect2, varscan2
- POFUT2 | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1321768975, COSV57957741; called by muse, mutect2, varscan2
- PRKCQ | c.97G>A p.V33I | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.144); catalogued as rs372791078; called by muse, mutect2, varscan2
- PRODH2 | c.823C>A p.Q275K (on ENST00000301175; = p.Q199K on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV56558258; called by muse, mutect2, varscan2
- PTPRG | c.3197G>C p.R1066T | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55643584; called by muse, mutect2, varscan2
- RC3H2 | c.3471_3473del p.T1158del | In Frame Del (DEL) | VAF 53/102 reads (52%) | catalogued as rs1237119138; called by pindel, varscan2
- RYR3 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as rs201612485, COSV66780005; called by muse, mutect2, varscan2
- SH3PXD2A | c.2587G>A p.A863T (on ENST00000369774 / NM_001365079.1; = p.A835T on NM_014631.2) | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as rs766798828, COSV60116246; called by muse, mutect2, varscan2
- SLC25A43 | c.627T>G p.C209W | Missense Mutation (SNP) | VAF 13/129 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99474645; called by muse, mutect2, varscan2
- SLFN11 | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 37/166 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.959); catalogued as rs752050667, COSV100390802; called by muse, mutect2, varscan2
- SNRNP200 | c.5978G>A p.R1993Q | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV55530229; called by muse, mutect2, varscan2
- STON1 | c.965T>C p.I322T | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV100562029; called by muse, mutect2, varscan2
- TBX3 | c.493T>A p.F165I | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99983668; called by muse, mutect2
- TGFBR1 | c.655G>T p.V219F | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs863223810, COSV66624839; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TLN1 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as COSV59203905; called by muse, mutect2, varscan2
- TTN | c.78908G>T p.R26303I (on ENST00000591111; = p.R18879I on NM_003319.4) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | PolyPhen benign (0.132); catalogued as rs773829475, COSV59880230; called by muse, mutect2, varscan2
- USP26 | c.1461dup p.G488Wfs*6 | Frame Shift Ins (INS) | VAF 40/106 reads (38%) | catalogued as rs761320003; called by mutect2, varscan2
- VN1R1 | c.384C>G p.H128Q | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.387); catalogued as COSV100320734; called by muse, mutect2, varscan2
- WNK1 | c.983G>A p.C328Y | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60025395; called by muse, mutect2, varscan2
- XKR6 | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376157005; called by muse, mutect2, varscan2
- ZNF221 | c.658C>T p.H220Y | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99240851; called by muse, mutect2, varscan2
- ZNF350 | c.1067C>A p.S356Y | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV99702617; called by muse, mutect2, varscan2
- ZNF467 | c.1075G>A p.D359N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs746160812, COSV100118024; called by mutect2, varscan2
- ZNF536 | c.1199C>T p.S400L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs746480413, COSV62818075; called by muse, mutect2, varscan2
- DIAPH2 | c.660dup p.Q221Tfs*6 | Frame Shift Ins (INS) | VAF 49/492 reads (10%) | called by mutect2, pindel
- FOXO4 | c.562_567delinsT p.G188Cfs*11 | Frame Shift Del (DEL) | VAF 18/39 reads (46%) | called by pindel, varscan2*
- PASD1 | c.1947dup p.V650Rfs*13 | Frame Shift Ins (INS) | VAF 18/132 reads (14%) | called by mutect2, pindel, varscan2
- PDS5B | c.2115_2116del p.I706Qfs*13 | Frame Shift Del (DEL) | VAF 12/106 reads (11%) | called by pindel, varscan2
- POLE | c.2332_2334del p.K778del | In Frame Del (DEL) | VAF 4/24 reads (17%) | called by pindel, varscan2
- PRKDC | c.7307_7308dup p.D2437Wfs*3 | Frame Shift Ins (INS) | VAF 9/90 reads (10%) | called by mutect2, pindel, varscan2
- ACSL4 | c.195C>T p.F65= (on ENST00000340800 / NM_022977.2; = p.F24= on NM_004458.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/269 reads (14%) | catalogued as rs200252463, COSV61613212; called by muse, mutect2, varscan2
- APOBEC3H | c.108G>A p.P36= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs1261730484, COSV100818858; called by muse, mutect2, varscan2
- ARHGAP39 | c.2070G>A p.S690= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs371616316; called by mutect2, varscan2
- CD53 | c.18G>A p.L6= | Silent (SNP) | VAF 30/246 reads (12%) | catalogued as rs1557818989, COSV54759950; called by muse, mutect2, varscan2
- CDC5L | c.1629A>G p.K543= | Silent (SNP) | VAF 20/209 reads (10%) | catalogued as COSV65175214; called by muse, mutect2, varscan2
- COL6A5 | c.6480G>A p.S2160= (on ENST00000312481; = p.S2156= on NM_153264.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/121 reads (12%) | catalogued as rs778454018, COSV55193358, COSV99592791; called by muse, mutect2, varscan2
- DBN1 | c.1410C>T p.P470= | Silent (SNP) | VAF 80/214 reads (37%) | catalogued as rs374007032, COSV99446078; called by muse, varscan2
- DCAF4L2 | c.546C>A p.I182= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV100151068, COSV60482036; called by muse, mutect2, varscan2
- DHFR2 | c.60C>T p.N20= | Silent (SNP) | VAF 43/113 reads (38%) | catalogued as rs199508022, COSV58933804; called by muse, mutect2, varscan2
- FOXD4L1 | c.465C>T p.I155= | Silent (SNP) | VAF 14/105 reads (13%) | catalogued as COSV99380053; called by muse, mutect2, varscan2
- GCKR | c.747C>T p.I249= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs371788464; called by muse, mutect2, varscan2
- GCNT2 | c.297C>T p.Y99= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV65456424; called by muse, mutect2, varscan2
- GPR101 | c.1233C>T p.S411= | Silent (SNP) | VAF 16/89 reads (18%) | catalogued as COSV53237299; called by muse, mutect2, varscan2
- GRHL2 | c.579C>T p.D193= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as rs144668624; called by mutect2, varscan2
- IL3 | c.393G>A p.T131= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs750120195, COSV57308338; called by muse, mutect2, varscan2
- ITPR3 | c.189C>T p.N63= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as COSV65405540; called by muse, mutect2, varscan2
- KIF26A | c.2025G>A p.P675= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs1184128383; called by muse, mutect2
- KRT37 | c.978G>A p.T326= | Silent (SNP) | VAF 15/41 reads (37%) | catalogued as rs768002570, COSV56656781; called by muse, mutect2, varscan2
- MAGEB1 | c.771C>T p.Y257= | Silent (SNP) | VAF 40/102 reads (39%) | catalogued as rs766373792, COSV66775251, COSV66775580; called by muse, mutect2, varscan2
- MCMBP | c.1587A>C p.P529= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as rs140316472, COSV100750127; called by muse, mutect2, varscan2
- MEGF6 | c.528C>T p.C176= | Silent (SNP) | VAF 19/29 reads (66%) | catalogued as rs41306996; called by muse, mutect2, varscan2
- MPPED2 | c.786C>T p.D262= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as rs771014072, COSV100813145, COSV63895997; called by muse, mutect2, varscan2
- MRC2 | c.669G>A p.E223= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as COSV100316448; called by muse, mutect2
- NDN | c.609C>T p.R203= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs1337000183, COSV59358373; called by muse, mutect2, varscan2
- PAH | c.1056T>C p.G352= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as CD992537, COSV100188240; called by muse, mutect2, varscan2
- PCDHGA6 | c.1908C>T p.D636= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs770239249, COSV53896503; called by muse, mutect2, varscan2
- RTN1 | c.1557G>A p.P519= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs763202784, COSV50718692; called by mutect2, varscan2
- SCN8A | c.1836C>T p.S612= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV61976317; called by muse, mutect2, varscan2
- TCERG1L | c.1128C>T p.R376= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs761953296, COSV64046353; called by muse, mutect2, varscan2
- TLL1 | c.1233C>T p.D411= | Silent (SNP) | VAF 13/93 reads (14%) | catalogued as rs764830976, COSV50261673; called by muse, mutect2, varscan2
- TOR4A | c.468G>A p.A156= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs1439124313, COSV100677758; called by muse, mutect2
- USO1 | c.2364A>C p.A788= | Silent (SNP) | VAF 30/196 reads (15%) | catalogued as COSV99362941; called by muse, mutect2
- WNT5A | c.1113G>A p.T371= | Silent (SNP) | VAF 6/25 reads (24%) | catalogued as rs751084010, COSV52836117; called by muse, mutect2, varscan2
- ZNF689 | c.696C>T p.P232= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV54907763; called by muse, mutect2, varscan2
- GRIK2 | c.2563-4343G>C | Intron (SNP) | VAF 23/137 reads (17%) | catalogued as COSV59711599; called by muse, mutect2, varscan2
- SLC22A17 | n.1321G>T | RNA (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
